Somatic mutation profile of tumor specimen TCGA-FA-A6HO-01A (aliquot TCGA-FA-A6HO-01A-11D-A31X-10) from TCGA case TCGA-FA-A6HO, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 58.4 years (21,330 days).
Specimen TCGA-FA-A6HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcb8ed2c-a9be-4cb7-978d-7bc40d51946e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-A6HO-10A (Blood Derived Normal), aliquot TCGA-FA-A6HO-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ed9235f-1fcf-41e8-9d8e-e1d4b6e77408

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 5, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARIH2 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs748510233, COSV62705711; called by mutect2, varscan2
- ASPH | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs755727749, COSV101064037; called by mutect2, varscan2
- ATP8A2 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.991); catalogued as rs1342694245, COSV99682673; called by muse, mutect2
- BTG1 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as rs1322444635, COSV55459545, COSV55460565; called by muse, mutect2, varscan2
- BTG2 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV99305848; called by muse, mutect2, varscan2
- CCDC81 | c.1723C>T p.R575* (on ENST00000445632 / NM_001156474.2; = p.R485* on NM_021827.4) | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs763581774, COSV99564489; called by muse, mutect2, varscan2
- CD79B | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50076054, COSV50076156, COSV50076492; called by muse, varscan2
- CSMD1 | c.7427G>A p.R2476Q (on ENST00000520002; = p.R2475Q on NM_033225.6) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs746088122, COSV59327160, COSV59373995; called by muse, mutect2, varscan2
- CSMD3 | c.3269C>T p.S1090F (on ENST00000297405 / NM_001363185.1; = p.S986F on NM_052900.3) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV52100273, COSV99838518; called by muse, mutect2, varscan2
- DAZAP1 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV51834488, COSV99245264; called by muse, mutect2, varscan2
- DCT | c.1388T>C p.V463A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs138244474; called by mutect2, varscan2
- EPSTI1 | c.805C>A p.Q269K (on ENST00000398762 / NM_001330543.2; = p.Q258K on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.592); catalogued as COSV100553028; called by muse, mutect2
- FBP2 | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100942162; called by muse, mutect2
- GOLGA3 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV52631877, COSV99210818; called by muse, mutect2, varscan2
- HTT | c.4849A>G p.M1617V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV100750951; called by muse, mutect2, varscan2
- IGHG2 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as rs775614208; called by muse, mutect2, varscan2
- KY | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101415007; called by muse, mutect2, varscan2
- MYO9B | c.2353C>T p.Q785* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV101261677; called by muse, mutect2, varscan2
- NEDD4 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs370701101; called by muse, mutect2, varscan2
- NOTUM | c.1184+2T>C p.X395_splice | Splice Site (SNP) | VAF 5/85 reads (6%) | catalogued as COSV101293805; called by muse, mutect2
- NR0B1 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV100973547; called by muse, mutect2
- PCYOX1L | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199217; called by muse, mutect2, varscan2
- PLXNB3 | c.3455C>T p.P1152L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV100737599; called by muse, mutect2, varscan2
- PSG8 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100126428; called by muse, mutect2, varscan2
- RASA3 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs776857082, COSV61868504; called by muse, mutect2, varscan2
- RNF10 | c.2381G>C p.R794T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100378767; called by mutect2, varscan2
- RNF128 | c.411G>C p.E137D | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs148223909, COSV99718296; called by muse, mutect2, varscan2
- SLC16A1 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.03); catalogued as rs746530125, COSV100856020; called by muse, mutect2, varscan2
- SYT1 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99696130; called by muse, mutect2, varscan2
- SYTL5 | c.1284G>T p.K428N | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99937404; called by muse, mutect2, varscan2
- TAGLN3 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV99845474; called by muse, mutect2
- TEX15 | c.427G>T p.V143F (on ENST00000256246; = p.V526F on NM_001350162.2) | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99821665; called by muse, mutect2
- TMEM108 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV100419128; called by muse, mutect2, varscan2
- USP4 | c.535C>G p.R179G | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99649449; called by muse, mutect2
- ZC3H12A | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as rs1451304050, COSV100897731; called by muse, mutect2, varscan2
- ZNF503 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100998008; called by muse, mutect2, varscan2
- IGHV4-59 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 69/556 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, varscan2
- AKAP11 | c.5019C>T p.A1673= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs201525107, COSV99214070; called by muse, mutect2, varscan2
- BTG1 | c.420G>A p.V140= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV99755597; called by muse, mutect2
- COL1A2 | c.1443C>T p.G481= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs757839011, COSV99800272; called by muse, mutect2, varscan2
- CRYBG2 | c.4392G>A p.V1464= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100366783; called by muse, mutect2, varscan2
- DUSP2 | c.451C>T p.L151= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1462467530, COSV99997025, COSV99997112; called by muse, mutect2
- IGHG2 | c.81C>T p.C27= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, varscan2
- IGHG3 | c.169C>T p.L57= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1199594226; called by muse, mutect2, varscan2
- PAQR6 | c.315C>T p.S105= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV99431320; called by muse, mutect2, varscan2
- ROBO2 | c.162G>A p.A54= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as rs983541438, COSV100166711, COSV59896407; called by muse, mutect2
- STK11 | c.583C>T p.L195= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1555738276, COSV100480631, COSV58827832; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNF | c.90C>T p.C30= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV101403213; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331261 C>T | 5'Flank (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
